Somatic mutation profile of tumor specimen TCGA-CV-A6K0-01B (aliquot TCGA-CV-A6K0-01B-21D-A31L-08) from TCGA case TCGA-CV-A6K0, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 58.8 years (21,488 days).
Specimen TCGA-CV-A6K0-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb14be0-750f-4cf6-b1f9-683c20ad16a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6K0-10A (Blood Derived Normal), aliquot TCGA-CV-A6K0-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47a5cab1-0145-452f-a64e-2f7c78a6c304

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX5 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs758477278, COSV65553024; called by muse, mutect2
- MAGEC1 | c.2159C>A p.S720Y | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV53571884, COSV99596794; called by muse, mutect2
- PCIF1 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs778640382, COSV100976122; called by muse, mutect2
- RAB7A | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99414397; called by muse, mutect2
- SLC27A4 | c.1322C>G p.P441R | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100307517; called by muse, mutect2
- SOCS6 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV67546016; called by muse, mutect2
- SYNE2 | c.15602G>C p.S5201T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100648621; called by muse, mutect2, varscan2
- CFAP74 | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- BAG6 | c.2553A>G p.T851= (on ENST00000676571; = p.T804= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as COSV99277812; called by muse, mutect2
- NRXN3 | c.1014C>T p.N338= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs761501427, COSV59723714; called by mutect2, varscan2
